Somatic mutation profile of tumor specimen TCGA-13-1496-01A (aliquot TCGA-13-1496-01A-01W-0545-08) from TCGA case TCGA-13-1496, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.7 years (23,993 days).
Specimen TCGA-13-1496-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a92832c-7b44-4ad8-85dd-63ad517c2b1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1496-10A (Blood Derived Normal), aliquot TCGA-13-1496-10A-01W-0545-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61de2edb-9892-450b-8515-39b91c0db35b

The open-access MAF lists 69 somatic variants for this specimen: 50 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 18, Nonsense Mutation 4, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 235/304 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGBL5 | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59938815; called by muse, mutect2, varscan2
- ANKRD26 | c.902C>T p.T301I | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs1450953755, COSV101066011; called by muse, mutect2, varscan2
- ANO4 | c.1823C>T p.T608I (on ENST00000392977 / NM_001286615.2; = p.T573I on NM_178826.4) | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.085); catalogued as rs757367090, COSV54610286, COSV54617710; called by muse, mutect2, varscan2
- APOB | c.12798C>G p.I4266M | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV51922606, COSV51957599; called by muse, mutect2, varscan2
- BDKRB2 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201760673, COSV60014969; called by muse, mutect2, varscan2
- CALCR | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 121/508 reads (24%) | catalogued as rs762940513, COSV64006530, COSV64006861; called by muse, mutect2, varscan2
- CCDC102B | c.87G>T p.M29I | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100101935; called by muse, varscan2
- CDS1 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 84/322 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV55691475; called by muse, mutect2, varscan2
- CELSR1 | c.5311G>A p.D1771N | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs772248884, COSV99416554; called by muse, mutect2, varscan2
- CYP39A1 | c.939T>A p.D313E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV51500115, COSV99242869; called by muse, mutect2
- DAB1 | c.1655G>T p.S552I (on ENST00000371231; = p.S519I on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/457 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64699386; called by muse, mutect2, varscan2
- DNAI2 | c.1087C>T p.H363Y | Missense Mutation (SNP) | VAF 92/182 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV56763358; called by muse, mutect2, varscan2
- ECHS1 | c.515-2A>T p.X172_splice | Splice Site (SNP) | VAF 4/11 reads (36%) | catalogued as COSV63907656; called by muse, mutect2, varscan2
- ERI3 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 135/807 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64833961; called by muse, varscan2
- EVC2 | c.2441C>T p.A814V | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.186); catalogued as rs868418252, COSV60405179; called by muse, mutect2, varscan2
- FABP2 | c.312T>A p.N104K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV56789521; called by muse, mutect2, varscan2
- FAM184A | c.2168C>T p.T723M | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs372303662, COSV58853616; called by muse, mutect2, varscan2
- FANCI | c.1832A>G p.D611G | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV55536312; called by muse, mutect2, varscan2
- FHOD3 | c.3920C>T p.A1307V (on ENST00000359247 / NM_001281739.3; = p.A1324V on NM_025135.5) | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.918); catalogued as rs141169952; called by muse, mutect2, varscan2
- HOXC6 | c.439A>C p.I147L | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV54538459; called by muse, mutect2, varscan2
- LIG3 | c.2128A>G p.I710V | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0.084); catalogued as rs967586901, COSV52011925; called by muse, mutect2, varscan2
- MAMLD1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 255/507 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.225); catalogued as COSV99475479; called by muse, mutect2, varscan2
- MIA3 | c.1164C>G p.F388L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV60519294; called by muse, mutect2, varscan2
- MXRA5 | c.975G>T p.E325D | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV54254461, COSV99476781; called by muse, mutect2, varscan2
- MYH15 | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV56322032; called by muse, mutect2, varscan2
- MYO18B | c.3761G>T p.R1254L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV59124937, COSV59152211; called by muse, mutect2, varscan2
- MYO7A | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs781922871, COSV68685692; ClinVar: likely benign; called by muse, mutect2, varscan2
- NIPBL | c.2582C>A p.S861* | Nonsense Mutation (SNP) | VAF 28/98 reads (29%) | catalogued as COSV56969874; called by muse, mutect2, varscan2
- OR5H2 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 194/446 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs183927815, COSV62350596, COSV62352177; called by muse, mutect2, varscan2
- PDCD5 | c.255G>C p.E85D | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV55679132; called by muse, mutect2
- PPP1R12B | c.2323A>T p.M775L | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.321); catalogued as COSV51790935; called by muse, mutect2, varscan2
- PPP1R3F | c.2074G>C p.E692Q | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as COSV99278328; called by muse, mutect2, varscan2
- PPP1R3F | c.2174G>C p.S725T | Missense Mutation (SNP) | VAF 129/453 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV99278330; called by muse, varscan2
- PTGDS | c.384C>A p.Y128* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | catalogued as COSV56401721; called by muse, mutect2, varscan2
- PTPRJ | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as rs1414420746, COSV69255169; called by muse, mutect2, varscan2
- RLF | c.3217A>G p.K1073E | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV65653509; called by muse, mutect2, varscan2
- SERPINA3 | c.904T>C p.S302P | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as rs1262530329, COSV67587402; called by muse, mutect2, varscan2
- SERPINA7 | c.73G>C p.G25R | Missense Mutation (SNP) | VAF 119/641 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV100568192, COSV100568370; called by muse, mutect2, varscan2
- SI | c.3100A>T p.I1034F | Missense Mutation (SNP) | VAF 88/474 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV52306078; called by muse, mutect2, varscan2
- SLC6A2 | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs1281511940, COSV54924833; called by muse, mutect2, varscan2
- SMCHD1 | c.1288C>T p.H430Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55271423; called by muse, mutect2, varscan2
- SUCLA2 | c.1397A>G p.E466G (on ENST00000643023; = p.E445G on NM_003850.3) | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.149); catalogued as COSV101074692; called by muse, mutect2, varscan2
- THBS2 | c.566G>C p.R189P | Missense Mutation (SNP) | VAF 50/241 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV64677686, COSV64682722; called by muse, mutect2, varscan2
- TTN | c.23015G>A p.R7672H (on ENST00000591111; = p.R6745H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/266 reads (19%) | PolyPhen probably damaging (0.911); catalogued as rs898421060, COSV100627763, COSV60416301; called by muse, mutect2, varscan2
- USP15 | c.2045A>C p.D682A (on ENST00000280377 / NM_001351159.2; = p.D653A on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.714); catalogued as COSV54800658; called by muse, mutect2, varscan2
- WDR45 | c.626C>A p.S209* (on ENST00000376372 / NM_001029896.2; = p.S210* on NM_007075.3) | Nonsense Mutation (SNP) | VAF 27/161 reads (17%) | catalogued as COSV59876216; called by muse, mutect2, varscan2
- ZNF586 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66972809; called by muse, mutect2, varscan2
- ZSWIM8 | c.3433G>C p.D1145H (on ENST00000605216 / NM_001242487.2; = p.D1150H on NM_015037.3) | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55218784; called by muse, mutect2, varscan2
- GTF2H2 | c.790G>C p.D264H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by mutect2, varscan2
- ARMCX1 | c.831C>T p.N277= | Silent (SNP) | VAF 250/584 reads (43%) | catalogued as rs782211130, COSV65705158; called by muse, mutect2, varscan2
- ATP23 | c.264C>T p.C88= | Silent (SNP) | VAF 103/474 reads (22%) | catalogued as rs201097826; called by muse, mutect2, varscan2
- COL22A1 | c.1524C>T p.G508= | Silent (SNP) | VAF 67/251 reads (27%) | catalogued as rs747852159, COSV100280790, COSV57323031; called by muse, mutect2, varscan2
- CSAG2 | c.381C>A p.P127= | Silent (SNP) | VAF 36/185 reads (19%) | called by muse, varscan2
- DCST2 | c.402C>T p.T134= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs753554045, COSV55054824; called by muse, mutect2, varscan2
- DRC1 | c.471C>T p.L157= | Silent (SNP) | VAF 46/216 reads (21%) | catalogued as COSV56534996, COSV56536704; called by muse, mutect2
- GPR17 | c.1044G>A p.P348= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs375979218; called by muse, mutect2, varscan2
- IGSF21 | c.1179C>T p.D393= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as rs766934886, COSV52131756; called by muse, mutect2, varscan2
- KCNS2 | c.1131C>T p.Y377= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as rs371574913; called by muse, mutect2, varscan2
- MAGI2 | c.2790C>A p.G930= | Silent (SNP) | VAF 18/172 reads (10%) | catalogued as COSV62706213; called by muse, mutect2, varscan2
- MYL2 | c.12G>A p.K4= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV104391445, COSV57408393; called by muse, mutect2, varscan2
- NAGLU | c.1464G>A p.P488= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as rs140956564; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- OR5A2 | c.723T>A p.T241= | Silent (SNP) | VAF 15/229 reads (7%) | catalogued as COSV100119654; called by muse, mutect2
- PKHD1 | c.10893T>C p.Y3631= | Silent (SNP) | VAF 135/634 reads (21%) | catalogued as rs1290859259, COSV64402908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP1R17 | c.243T>C p.F81= | Silent (SNP) | VAF 40/164 reads (24%) | catalogued as COSV59612873; called by muse, mutect2, varscan2
- PPP1R3F | c.2220G>A p.K740= | Silent (SNP) | VAF 182/624 reads (29%) | catalogued as COSV99278333, COSV99278645; called by muse, varscan2
- WNK3 | c.3363C>A p.L1121= | Silent (SNP) | VAF 136/440 reads (31%) | catalogued as COSV63612360, COSV63616355; called by muse, mutect2, varscan2
- ZNF334 | c.1515T>C p.S505= | Silent (SNP) | VAF 53/227 reads (23%) | catalogued as COSV61620549; called by muse, mutect2, varscan2
- PAK3 | c.277-1619A>T | Intron (SNP) | VAF 46/211 reads (22%) | catalogued as COSV53281831; called by muse, mutect2, varscan2
